CCDI case PBBTND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/d2e1b309-64a8-45e9-8648-8d3e9e8cfc91

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Mandible; Age at diagnosis: 18.8 years (6,876 days).

Biospecimens (3 samples)
- Sample 0DHOH0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHOIX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHOJ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
